Somatic mutation profile of tumor specimen TCGA-DU-A7T8-01A (aliquot TCGA-DU-A7T8-01A-21D-A34J-08) from TCGA case TCGA-DU-A7T8, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Mixed glioma; Tissue or organ of origin: Cerebrum; Tumor grade: G3; Age at diagnosis: 35.9 years (13,108 days).
Specimen TCGA-DU-A7T8-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 26385425-68c3-4628-b257-857e2f6afa04.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DU-A7T8-10A (Blood Derived Normal), aliquot TCGA-DU-A7T8-10A-01D-A34M-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0dc2a064-890f-46b9-94c9-70621a60f3c3

The open-access MAF lists 15 somatic variants for this specimen: 13 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 11, Silent 2, Frame Shift Del 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 24/80 reads (30%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- TP53 | c.358A>G p.K120E | Missense Mutation (SNP) | VAF 33/59 reads (56%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121912658, CM921039, COSV52676498, COSV52692352, COSV53551619, COSV53685479; ClinVar: likely pathogenic / uncertain significance / pathogenic; called by muse, mutect2, varscan2
- ATRX | c.1373C>A p.S458* | Nonsense Mutation (SNP) | VAF 140/155 reads (90%) | catalogued as COSV100969911, COSV100971604; called by muse, mutect2, varscan2
- CASP8 | c.991G>A p.A331T (on ENST00000432109 / NM_033355.3; = p.A348T on NM_001228.4) | Missense Mutation (SNP) | VAF 39/104 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.082); catalogued as COSV99631057; called by muse, mutect2, varscan2
- CLMN | c.2117A>G p.E706G | Missense Mutation (SNP) | VAF 21/60 reads (35%) | SIFT tolerated (0.06); PolyPhen benign (0.194); catalogued as rs145305362; called by muse, mutect2, varscan2
- CYP11B2 | c.38C>T p.A13V | Missense Mutation (SNP) | VAF 97/147 reads (66%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as rs755076671, COSV59995197, COSV59995273; called by muse, mutect2, varscan2
- FHOD1 | c.1615C>T p.L539F | Missense Mutation (SNP) | VAF 42/109 reads (39%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.946); catalogued as COSV99264604; called by muse, mutect2, varscan2
- GPR132 | c.460C>T p.R154C | Missense Mutation (SNP) | VAF 35/68 reads (51%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs753138254, COSV100317783; called by muse, mutect2, varscan2
- GRIA4 | c.883A>G p.K295E | Missense Mutation (SNP) | VAF 22/61 reads (36%) | SIFT tolerated (0.05); PolyPhen benign (0.297); catalogued as rs1176642973, COSV99231891; called by muse, mutect2, varscan2
- MDN1 | c.11282T>G p.I3761S | Missense Mutation (SNP) | VAF 61/147 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.844); catalogued as COSV101021913; called by muse, mutect2, varscan2
- VIL1 | c.2252A>G p.D751G | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT tolerated (0.34); PolyPhen benign (0.013); catalogued as COSV99945926; called by muse, mutect2, varscan2
- ZSCAN20 | c.2371G>C p.E791Q | Missense Mutation (SNP) | VAF 26/103 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.85); catalogued as COSV100792767, COSV63681972; called by muse, mutect2, varscan2
- APPL1 | c.1655del p.L552* | Frame Shift Del (DEL) | VAF 20/55 reads (36%) | called by mutect2, pindel, varscan2
- KIAA1217 | c.2535C>T p.A845= | Silent (SNP) | VAF 4/44 reads (9%) | catalogued as rs1032651707, COSV56821064; called by muse, mutect2
- MAST1 | c.1716T>C p.A572= | Silent (SNP) | VAF 7/92 reads (8%) | catalogued as COSV99263836; called by muse, mutect2
